TARGET case TARGET-15-SJMPAL012418 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/a983c20c-f2f5-4fac-b9b9-b3fdcbc8505a

Demographics
Sex at birth: male; Age at index: 16 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.3 years (5,940 days); Year of diagnosis: 2002.

Follow-up (1 entry)
- Follow-up contact recording only the day: follow-up.

Biospecimens (5 samples)
- Samples TARGET-15-SJMPAL012418-09A, TARGET-15-SJMPAL012418-09A.1, TARGET-15-SJMPAL012418-09A.2, TARGET-15-SJMPAL012418-09A.3 (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012418-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: St. Jude
- Karyotype: 46,XY,t(10;11)(q22;q23)[20]
- WHO ALAL Classification: MLL
- WHO Dx: MLL
